Gene-level copy-number profile of tumor specimen ALCH-B2SA-TTP1-A from ALCHEMIST case ALCH-B2SA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,272 days).
Specimen ALCH-B2SA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ac707f9d-b5e7-496d-9bef-37e78ccccb22.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/eebec03c-fa30-43cb-b5cf-385b5ff7c09a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 661; copy number 1: 15,836; copy number 2: 35,603; copy number 3: 6,537; copy number 4: 120; copy number 5: 99; copy number 6: 4; copy number 7: 1; copy number 8: 33.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:238,100,340–238,133,287, 1 gene: ESPNL.
- chr7:98,211,439–98,215,457, 1 gene (within-gene range 0–1): BHLHA15.
- chr7:128,830,406–128,910,719, 5 genes (within-gene range 0–1): FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB.
- chr8:22,024,125–22,048,809, 2 genes: NPM2, FGF17.
- chr8:31,497,423–31,598,204, 2 genes: AC068672.1, RNA5SP261.
- chr9:18,573,306–18,573,379, 1 gene (within-gene range 0–1): MIR3152.
- chr11:3,189,546–3,232,838, 5 genes: AC108448.1, MRGPRG, MRGPRG-AS1, MRGPRE, AC109309.1.
- chr12:54,802,746–54,803,589, 1 gene: VDAC1P5.
- chr14:100,143,957–100,159,645, 1 gene (within-gene range 0–2): DEGS2.
- chr14:104,579,764–104,590,515, 2 genes (within-gene range 0–2): C14orf180, BX927359.1.
- chr15:25,178,738–25,243,695, 36 genes (within-gene range 0–1): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr17:81,451,104–81,461,937, 2 genes (within-gene range 0–2): MIR3186, AC110285.4.
- chr18:79,395,856–79,529,325, 6 genes: NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:5,720,637–5,791,225, 4 genes: CATSPERD, PRR22, AC011499.1, DUS3L.
- chr21:44,200,602–44,327,376, 8 genes: AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1, AIRE, PFKL.
- chr22:20,115,938–20,321,203, 12 genes (within-gene range 0–3): RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.
- chr22:45,875,932–45,891,438, 2 genes: BX324167.2, BX324167.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 137 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene, copy number 5: AC112203.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:33,924,227–37,596,059, 87 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:5,292,388–6,220,759, 33 genes, copy number 8: UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3.
- chr21:10,482,738–13,120,807, 11 genes, copy number 5 (within-gene range 2–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:20,348,758–20,354,387, 1 gene, copy number 7 (within-gene range 1–7): AC007731.5.

Autosomal genes at a single copy (total copy number 1): 13,591. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
